Somatic mutation profile of tumor specimen TCGA-CR-6473-01A (aliquot TCGA-CR-6473-01A-11D-1870-08) from TCGA case TCGA-CR-6473, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; Tumor grade: G3; Age at diagnosis: 68.1 years (24,857 days).
Specimen TCGA-CR-6473-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94fcedbe-07d4-4416-b9d6-0269ed105425.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6473-10A (Blood Derived Normal), aliquot TCGA-CR-6473-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbfe8890-a6b7-4bb7-b3fb-70997357eee0

The open-access MAF lists 96 somatic variants for this specimen: 74 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 21, Nonsense Mutation 6, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.3406C>G p.L1136V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99287681; called by muse, mutect2, varscan2
- ARFGAP3 | c.1148C>A p.T383N | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99605062; called by muse, mutect2, varscan2
- ASPM | c.8674C>T p.H2892Y | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.119); catalogued as COSV99659329; called by muse, mutect2, varscan2
- BICD1 | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.076); catalogued as COSV99861903; called by muse, mutect2, varscan2
- BPIFB3 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as COSV100972273; called by muse, mutect2, varscan2
- BRCA2 | c.10024G>A p.E3342K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs28897761, COSV66337145; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- BTN3A3 | c.938-1G>A p.X313_splice | Splice Site (SNP) | VAF 54/131 reads (41%) | catalogued as COSV99764732; called by muse, mutect2, varscan2
- C2CD6 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99631692; called by muse, mutect2, varscan2
- CEP135 | c.1352A>G p.E451G | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99954040; called by muse, mutect2, varscan2
- CFAP70 | c.2845G>C p.E949Q | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100160100; called by muse, mutect2, varscan2
- CNNM2 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as COSV100881636; called by muse, mutect2, varscan2
- CWF19L1 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1245726848, COSV100821433, COSV62499512; called by muse, mutect2, varscan2
- DCP1A | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99587752; called by muse, mutect2
- DMBT1 | c.5344G>T p.V1782L (on ENST00000338354 / NM_001377530.1; = p.V1025L on NM_004406.3) | Missense Mutation (SNP) | VAF 142/364 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100351872; called by muse, mutect2, varscan2
- DNAH7 | c.12040C>T p.R4014* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as rs554368145, COSV100413580, COSV100418237; called by muse, mutect2, varscan2
- DNAL1 | c.150C>T p.C50= | Splice Region (SNP) | VAF 140/348 reads (40%) | catalogued as COSV100225700; called by muse, mutect2, varscan2
- EIF2AK4 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV99773912; called by muse, mutect2, varscan2
- ENTPD3 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | catalogued as COSV100088392, COSV57194644; called by muse, mutect2, varscan2
- FLG | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 265/613 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs763804160, COSV100910374, COSV64238603; called by muse, mutect2, varscan2
- FSCB | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138964489; called by muse, mutect2, varscan2
- FYB2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100599132, COSV58585849; called by muse, mutect2, varscan2
- GFOD2 | c.1053C>G p.I351M | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99263318; called by muse, mutect2, varscan2
- GRAMD1A | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs777238052, COSV58766203; called by muse, mutect2, varscan2
- GRIA2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs142538282, COSV52402874; called by muse, mutect2, varscan2
- GTF2H1 | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99786237; called by muse, mutect2, varscan2
- HIRA | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV99599818; called by muse, mutect2, varscan2
- IGF2R | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs577548757, COSV100806733; called by muse, mutect2, varscan2
- INSYN1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs772102988, COSV101138674, COSV101138793; called by muse, mutect2, varscan2
- KALRN | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs752649073, COSV99561784; called by muse, mutect2, varscan2
- KCNA6 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99768257; called by muse, mutect2, varscan2
- KCNC1 | c.1157A>G p.N386S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.999); catalogued as COSV99788658; called by muse, mutect2, varscan2
- KMT2D | c.5704G>T p.E1902* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as COSV56495537, COSV99976868; called by muse, mutect2, varscan2
- KRT73 | c.999G>C p.Q333H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988211; called by muse, mutect2, varscan2
- LIN37 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.235); catalogued as COSV99137372; called by muse, mutect2, varscan2
- LRRC73 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV52503784, COSV99446071; called by muse, mutect2, varscan2
- MAP3K9 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV101173425; called by muse, mutect2, varscan2
- MARCHF3 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100427663; called by muse, mutect2, varscan2
- MBTPS1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs377692604; called by muse, mutect2, varscan2
- MC5R | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201991586, COSV61255313; called by muse, mutect2, varscan2
- MFAP3 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100491475; called by muse, mutect2, varscan2
- MUC16 | c.8296G>A p.E2766K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV67478448; called by muse, mutect2, varscan2
- MUC16 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV101197644; called by muse, mutect2, varscan2
- MUC16 | c.5595G>C p.L1865F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101197645, COSV67480500; called by muse, mutect2, varscan2
- MUC16 | c.5072G>A p.R1691K | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs773067737, COSV67491878; called by muse, mutect2, varscan2
- MUC16 | c.4925G>T p.G1642V | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV101197647; called by muse, mutect2, varscan2
- MUC16 | c.4225G>C p.E1409Q | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.331); catalogued as COSV67456004; called by muse, mutect2, varscan2
- NLRC5 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1428109693, COSV99346286; called by muse, mutect2, varscan2
- OR12D2 | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.068); catalogued as COSV101011072, COSV65830182; called by muse, varscan2
- PCDH15 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as rs1365986192, COSV100213921, COSV57390894; called by muse, mutect2, varscan2
- PDE1C | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs377062465, COSV58518602; called by muse, mutect2, varscan2
- PHLDB2 | c.1749A>T p.R583S | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV101208360; called by muse, mutect2, varscan2
- PIPOX | c.897C>A p.S299R | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100037826; called by muse, mutect2, varscan2
- PPHLN1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV99871384; called by muse, mutect2, varscan2
- PSG9 | c.711G>A p.P237= | Splice Region (SNP) | VAF 109/266 reads (41%) | catalogued as rs4028446, COSV99391977; called by muse, mutect2, varscan2
- PSMA1 | c.19A>T p.K7* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs1214450755, COSV101335521; called by muse, mutect2, varscan2
- PSPC1 | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV100142108; called by muse, mutect2, varscan2
- R3HDM1 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99925527; called by muse, mutect2, varscan2
- RECQL5 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs548064379, COSV99502636; called by muse, mutect2, varscan2
- RPTN | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 106/226 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV100285184; called by muse, mutect2, varscan2
- SATB1 | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100112846; called by muse, mutect2, varscan2
- SCN9A | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV57628647; called by muse, mutect2, varscan2
- SENP5 | c.2229G>C p.R743S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100051713; called by muse, mutect2, varscan2
- TBC1D22A | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as rs776778660, COSV100452527; called by muse, mutect2, varscan2
- TCHH | c.5686C>T p.R1896C | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.799); catalogued as rs200484504, COSV64276554; called by muse, mutect2, varscan2
- TMEM164 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1457996767, COSV99911278; called by muse, mutect2, varscan2
- TSGA10 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs201326323, COSV100747407; called by muse, mutect2, varscan2
- TTLL3 | c.2605C>T p.R869* | Nonsense Mutation (SNP) | VAF 47/58 reads (81%) | catalogued as rs373552783; called by muse, mutect2, varscan2
- ZNF667 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV99409941; called by muse, mutect2
- IGLJ5 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI14 | c.2022_2053del p.E674Dfs*10 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel
- TADA2A | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TSSK3 | c.569_570del p.K190Rfs*2 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | called by mutect2, pindel, varscan2
- UPF2 | c.2625del p.G876Efs*97 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- ZNF804A | c.1622dup p.N541Kfs*2 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.693C>T p.I231= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100664651; called by muse, mutect2, varscan2
- CLDN1 | c.541C>T p.L181= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs1277439546, COSV55045398; called by muse, mutect2, varscan2
- DNMT3B | c.840G>A p.L280= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as rs1200165970, COSV99140414; called by muse, mutect2, varscan2
- DYNC1H1 | c.12495C>T p.P4165= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs778319883, COSV64135793; ClinVar: likely benign; called by muse, mutect2, varscan2
- EDDM3A | c.435C>T p.I145= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV100473271; called by muse, varscan2
- FAM178B | c.1902G>A p.T634= (on ENST00000490605 / NM_001122646.3; = p.T74= on NM_016490.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs145363262; called by muse, mutect2, varscan2
- FEM1A | c.1317G>A p.A439= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs1289383470, COSV99521349; called by muse, mutect2, varscan2
- GNL3 | c.48T>C p.H16= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as rs772280295, COSV101187200; called by muse, mutect2, varscan2
- GRIA3 | c.945G>A p.L315= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV99988715; called by muse, mutect2, varscan2
- HNRNPL | c.1077C>T p.Y359= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs769521344, COSV99669886; called by muse, varscan2
- IGKV1-27 | c.216T>C p.A72= | Silent (SNP) | VAF 77/177 reads (44%) | called by muse, mutect2, varscan2
- ITIH1 | c.2514C>T p.I838= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs143276781, COSV56254113; called by muse, mutect2, varscan2
- MUC16 | c.6219G>A p.L2073= | Silent (SNP) | VAF 65/170 reads (38%) | catalogued as COSV101197642; called by muse, mutect2, varscan2
- OR52B2 | c.672C>T p.L224= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101603920; called by muse, mutect2, varscan2
- PPP1R42 | c.372G>A p.E124= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV100220998; called by muse, mutect2, varscan2
- PTCD2 | c.1095G>A p.T365= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as rs754223635, COSV100348698; called by muse, mutect2, varscan2
- SUCO | c.2478A>G p.P826= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99741805; called by muse, mutect2
- TPO | c.750A>G p.K250= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100219484; called by muse, mutect2, varscan2
- TRMT2A | c.657G>A p.K219= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1412050077, COSV99349692; called by muse, mutect2, varscan2
- USP19 | c.2544C>T p.A848= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV100025731; called by muse, mutect2, varscan2
- ZIC2 | c.1032C>T p.F344= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100891748; called by muse, mutect2, varscan2
- ZNF467 | chr7:149776073 C>T | 5'Flank (SNP) | VAF 10/20 reads (50%) | catalogued as rs763081613, COSV50488445; called by muse, mutect2, varscan2
